Gene-level copy-number profile of tumor specimen TCGA-24-1924-01A from TCGA case TCGA-24-1924, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.2 years (23,801 days).
Specimen TCGA-24-1924-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.77b5d8df-a1b5-4cb2-90aa-26878994b48d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1924-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/967583e1-f045-481a-9396-0375750d4f71

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,594; copy number 2: 16,012; copy number 3: 21,845; copy number 4: 9,681; copy number 5: 6,498; copy number 6: 2,862; copy number 7: 1,163; copy number 8: 148; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:55,655,604–55,706,422, 2 genes: SLC6A2, AC136621.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,314 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,140,263–45,750,653, 495 genes, copy number 7 (broad region; genes not listed).
- chr4:74,308,470–75,990,962, 31 genes, copy number 8: EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, AC098825.1, HSPE1P23, PARM1, PARM1-AS1, AC110760.1, LINC02562, AC110760.2, AC093870.1, AC025244.1, AC025244.2, LINC02483, AC096759.1, AC096759.2, RCHY1, THAP6, ODAPH, CDKL2, G3BP2, Y_RNA, USO1, AC110615.1, RNU2-16P, PPEF2, NAAA, SDAD1.
- chr6:77,460,924–77,927,028, 3 genes, copy number 7: HTR1B, RPS6P7, MEI4.
- chr7:135,774,521–136,488,317, 8 genes, copy number 7 (within-gene range 5–7): AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1, ZP3P2.
- chr7:136,713,871–136,715,188, 1 gene, copy number 7: PSMC1P3.
- chr7:152,590,641–153,748,986, 14 genes, copy number 8 (within-gene range 8–11): AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P, ACTR3B, AC006348.1, AC079809.1, LINC01287, AC073236.1, PAXBP1P1, AC005998.1.
- chr7:153,968,665–154,063,325, 3 genes, copy number 11: AC005588.1, AC006019.3, AC006019.1.
- chr8:37,908,738–42,332,460, 103 genes, copy number 8 (broad region; genes not listed).
- chr8:129,832,301–131,317,632, 21 genes, copy number 7: AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1.
- chr9:1,977,784–19,049,358, 202 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr15:70,556,521–73,305,205, 68 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr18:21,928,985–49,048,474, 363 genes, copy number 7 (broad region; genes not listed).
- chr18:49,049,687–49,126,479, 2 genes, copy number 7: MIR4744, AC016866.2.

Autosomal genes at a single copy (total copy number 1): 1,151. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
